Somatic mutation profile of tumor specimen MP2PRT-PATBKS-TMP1-A (aliquot MP2PRT-PATBKS-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATBKS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,277 days).
Specimen MP2PRT-PATBKS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a67b8fc-4197-430d-91be-dc3f4a68c1d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBKS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBKS-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28280776-497b-4d9e-8d01-4a450cd7a4d5

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 121/356 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FOXN4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 243/505 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs377055340, COSV54496206; called by muse, mutect2, varscan2
- FRMPD2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 137/327 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs148640858; called by muse, mutect2, varscan2
- FSTL5 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV60231539; called by muse, mutect2, varscan2
- LTBP1 | c.3151G>C p.G1051R (on ENST00000404816 / NM_206943.4; = p.G725R on NM_000627.4) | Missense Mutation (SNP) | VAF 160/385 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99698436; called by muse, mutect2, varscan2
- STARD8 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 297/638 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs202226918; called by muse, mutect2, varscan2
- NOX3 | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); called by muse, mutect2
- MUC12 | c.8130C>T p.T2710= (on ENST00000379442; = p.T2567= on NM_001164462.1) | Silent (SNP) | VAF 278/630 reads (44%) | catalogued as rs775399444; called by muse, mutect2, varscan2
